Somatic mutation profile of tumor specimen TCGA-W3-AA1W-06A (aliquot TCGA-W3-AA1W-06A-11D-A38G-08) from TCGA case TCGA-W3-AA1W, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-W3-AA1W-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e8a3221-8754-4747-ab5f-47d26cea362f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA1W-10A (Blood Derived Normal), aliquot TCGA-W3-AA1W-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dea655a-bfa5-441c-aaf9-cdb92771023f

The open-access MAF lists 836 somatic variants for this specimen: 538 protein-altering or splice-affecting, 281 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 492, Silent 281, Nonsense Mutation 28, Splice Region 13, Intron 9, RNA 5, Splice Site 4, 5'UTR 2, Frame Shift Del 1, 5'Flank 1.

Variants (750 of 836; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 66/197 reads (34%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs781223647, CM001804, COSV100240460, COSV56332304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.7390C>T p.R2464C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs61751286, CM070317, COSV54626153; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1826A>G p.N609S | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV100229302; called by muse, mutect2, varscan2
- A2ML1 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV55292383; called by muse, mutect2, varscan2
- ABCB4 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755238300, COSV99711068; called by muse, mutect2, varscan2
- ABCC11 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs769721654, COSV100751044; called by muse, mutect2, varscan2
- ABCC4 | c.987A>C p.K329N | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100972697; called by muse, mutect2, varscan2
- ABLIM1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1020523742, COSV99522613; called by muse, mutect2, varscan2
- ACSL4 | c.1977C>T p.A659= (on ENST00000340800 / NM_022977.2; = p.A618= on NM_004458.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100538935; called by muse, mutect2, varscan2
- ACSM1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99533326; called by muse, mutect2, varscan2
- ACSM1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV54635872; called by muse, mutect2, varscan2
- ACTC1 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV51761459, COSV99291727; called by muse, mutect2, varscan2
- ADAM18 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV55846857; called by muse, mutect2
- ADAMTS14 | c.3415G>A p.G1139R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100941790; called by muse, mutect2, varscan2
- ADAMTS18 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1487148464, COSV99271040; called by muse, mutect2, varscan2
- ADAMTS20 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs748211259, COSV101166376; called by muse, mutect2, varscan2
- ADGRV1 | c.9130C>T p.Q3044* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as rs1282761845, COSV67983279, COSV67985701; called by muse, mutect2
- ADGRV1 | c.12256C>T p.P4086S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67986490; called by muse, mutect2, varscan2
- ADGRV1 | c.14846C>T p.S4949L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV67991037; called by muse, mutect2, varscan2
- ADH1B | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100520839; called by muse, mutect2, varscan2
- ADH1B | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1353041149, COSV59298672; called by muse, mutect2, varscan2
- ADIPOR2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs145541863; called by muse, mutect2, varscan2
- AFP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs781592078, COSV56927383; called by muse, mutect2, varscan2
- AGO1 | c.1264-1G>A p.X422_splice | Splice Site (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100940902; called by muse, mutect2, varscan2
- AHNAK | c.10808C>T p.P3603L | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1452306209, COSV99949006; called by muse, mutect2, varscan2
- AKR1B15 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101423403; called by muse, mutect2, varscan2
- ALPK2 | c.2657T>G p.M886R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV100864725; called by muse, mutect2, varscan2
- ANK3 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99781753; called by muse, mutect2, varscan2
- ANKDD1A | c.1065G>A p.K355= | Splice Region (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100731272; called by muse, mutect2, varscan2
- ANKMY1 | c.1444T>C p.S482P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99802959; called by muse, mutect2
- ANXA7 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs867363009, COSV100873495; called by muse, mutect2, varscan2
- APOB | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.593); catalogued as rs867683513, COSV99267294; called by muse, mutect2, varscan2
- ARHGAP26 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV99191252; called by muse, mutect2, varscan2
- ARHGAP32 | c.5548C>T p.P1850S (on ENST00000310343 / NM_001378025.1; = p.P1501S on NM_014715.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV100088813; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARMS2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.018); catalogued as rs768487894, COSV101600752; called by muse, mutect2, varscan2
- ARNTL | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100724835; called by mutect2, varscan2
- ASB15 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV99306900; called by muse, mutect2, varscan2
- ASGR2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.582); catalogued as rs772101733, COSV99643136; called by muse, varscan2
- ASXL3 | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52479082; called by muse, mutect2, varscan2
- ATG16L1 | c.1714C>T p.L572F (on ENST00000392017 / NM_030803.7; = p.L553F on NM_017974.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV100731370; called by muse, mutect2, varscan2
- ATXN1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs758093377, COSV55209499; called by muse, mutect2, varscan2
- B3GALT1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs755628484, COSV59908038; called by muse, mutect2, varscan2
- BAG6 | c.3049C>T p.P1017S (on ENST00000676571; = p.P970S on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs770643352, COSV99277481; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as COSV100863886; called by muse, mutect2, varscan2
- BTBD11 | c.2288C>T p.S763F (on ENST00000280758 / NM_001018072.2; = p.S300F on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99776657; called by muse, mutect2, varscan2
- BTNL8 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99180553; called by muse, mutect2, varscan2
- CABCOCO1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs376865516; called by muse, mutect2
- CACNA1E | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs576927174, COSV62381521; called by muse, mutect2
- CADM2 | c.1217G>A p.G406E (on ENST00000407528 / NM_001167674.2; = p.G408E on NM_153184.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67367805; called by muse, mutect2, varscan2
- CALCR | c.667C>T p.P223S (on ENST00000649521 / NM_001164737.2; = p.P207S on NM_001742.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as COSV100810792; called by muse, mutect2, varscan2
- CAMSAP2 | c.3070C>T p.P1024S (on ENST00000236925 / NM_001297707.2; = p.P1013S on NM_203459.3) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99374055; called by muse, mutect2, varscan2
- CARD6 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV54567026; called by muse, mutect2, varscan2
- CARD6 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as COSV99621163; called by muse, mutect2, varscan2
- CBLL2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60369355; called by muse, mutect2, varscan2
- CBY2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60118008; called by muse, mutect2, varscan2
- CCAR2 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV99374273; called by muse, mutect2, varscan2
- CCDC105 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52963615; called by muse, mutect2
- CCDC174 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV100358686; called by muse, mutect2
- CCR2 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as rs1301541790, COSV99432700; called by muse, mutect2, varscan2
- CCR2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV52749045; called by muse, mutect2, varscan2
- CD163L1 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs151328196; called by muse, mutect2, varscan2
- CD300LG | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1428641337, COSV99517591; called by muse, mutect2, varscan2
- CD33 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs1368347663, COSV99220706; called by muse, mutect2, varscan2
- CD6 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100533210; called by muse, mutect2, varscan2
- CD8B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs767948136, COSV58928811; called by muse, mutect2, varscan2
- CDC25C | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100086852, COSV60401230; called by muse, varscan2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, mutect2, varscan2
- CEP128 | c.2831A>C p.K944T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs563405334, COSV99825656; called by muse, mutect2, varscan2
- CFTR | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.579); catalogued as COSV99138629; called by muse, mutect2, varscan2
- CHL1 | c.1570C>T p.P524S (on ENST00000397491 / NM_001253387.1; = p.P540S on NM_006614.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV99850147, COSV99852032; called by muse, mutect2, varscan2
- CHRM3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382696054, COSV55089720; called by muse, mutect2, varscan2
- CHTOP | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV100904716; called by muse, mutect2, varscan2
- CIC | c.3014C>T p.T1005I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99360123; called by muse, mutect2, varscan2
- CKMT1A | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs754073482, COSV100787705; called by muse, varscan2
- CKMT1B | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs550622093, COSV55853716; called by muse, mutect2, varscan2
- CLMN | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100112777; called by muse, mutect2, varscan2
- CMIP | c.329C>T p.S110F (on ENST00000537098 / NM_198390.2; = p.S16F on NM_030629.3) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs1299870490, COSV101607036; called by muse, mutect2, varscan2
- CNDP1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV100722493; called by muse, mutect2, varscan2
- CNOT1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100409869; called by muse, mutect2, varscan2
- CNTN4 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639572; called by muse, mutect2, varscan2
- CNTNAP1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226870; called by muse, mutect2, varscan2
- COL11A1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100617840, COSV62197579; called by muse, mutect2, varscan2
- COL11A1 | c.1845G>A p.R615= | Splice Region (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100617842; called by muse, mutect2, varscan2
- COL28A1 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV101258867; called by muse, mutect2, varscan2
- COL3A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58581957; called by muse, mutect2
- COL3A1 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV58597358; called by muse, mutect2, varscan2
- COL4A1 | c.4399C>T p.L1467F | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs11545878, COSV101011448; called by muse, mutect2, varscan2
- COL6A2 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886042922, COSV100154091, COSV56018285; ClinVar: uncertain significance; called by muse, mutect2
- COL7A1 | c.4090C>T p.P1364S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60393194, COSV60402173; called by muse, mutect2, varscan2
- CP | c.2079G>A p.G693= | Splice Region (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99224379; called by muse, mutect2
- CPS1 | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV99243824; called by muse, mutect2, varscan2
- CRB1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66330452; called by muse, mutect2, varscan2
- CREB3L3 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs770823718, COSV99314429; called by mutect2, varscan2
- CRIP3 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780835146, COSV99240537; called by muse, mutect2, varscan2
- CRYBG2 | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100366915; called by muse, mutect2, varscan2
- CSAD | c.1048G>A p.G350R (on ENST00000444623 / NM_001244705.2; = p.G377R on NM_015989.5) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914956; called by muse, mutect2, varscan2
- CSMD1 | c.3619C>T p.Q1207* (on ENST00000520002; = p.Q1206* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs1164263475, COSV59355333; called by muse, mutect2
- CSMD2 | c.7757C>T p.P2586L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV53945709, COSV99593969; called by muse, mutect2, varscan2
- CSPG4 | c.4511C>T p.S1504F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100414036; called by muse, mutect2
- CTSV | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99414425; called by muse, mutect2, varscan2
- CUL2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV101039259; called by muse, mutect2, varscan2
- CUL4A | c.1379G>A p.R460K (on ENST00000375440 / NM_001008895.4; = p.R360K on NM_003589.3) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417474; called by muse, mutect2, varscan2
- CYLC2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV100872535, COSV66336699; called by muse, mutect2
- CYP11B1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV52830232; called by muse, mutect2, varscan2
- CYP24A1 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV99398534; called by muse, mutect2, varscan2
- CYP2E1 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs767486762, COSV99428917, COSV99429175; called by muse, mutect2, varscan2
- CYP4F11 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99931022; called by muse, mutect2, varscan2
- CYP4X1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV64149516; called by muse, mutect2, varscan2
- CYP4X1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754528907, COSV64151069; called by muse, mutect2, varscan2
- CYP4X1 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV64150371; called by muse, mutect2, varscan2
- DACT1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV60019433; called by muse, mutect2, varscan2
- DDI1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV56372611; called by muse, mutect2, varscan2
- DDIT4L | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV99913958; called by muse, mutect2
- DGAT2L6 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs140805163, COSV60717212; called by muse, mutect2, varscan2
- DKK2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53403493; called by muse, mutect2, varscan2
- DLC1 | c.4091C>T p.P1364L (on ENST00000276297 / NM_001348081.2; = p.P927L on NM_006094.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV99364878; called by muse, mutect2, varscan2
- DLC1 | c.4090C>T p.P1364S (on ENST00000276297 / NM_001348081.2; = p.P927S on NM_006094.5) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV99364880; called by muse, mutect2, varscan2
- DMAP1 | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 26/174 reads (15%) | catalogued as COSV100261810; called by muse, mutect2, varscan2
- DMGDH | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99669396; called by muse, mutect2, varscan2
- DNAH10 | c.8405G>A p.G2802E (on ENST00000409039; = p.G2741E on NM_207437.3) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV69001987; called by muse, mutect2, varscan2
- DNAH11 | c.13246G>A p.E4416K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs764231441, COSV100180301; called by muse, mutect2, varscan2
- DNAH17 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV101103177; called by muse, mutect2, varscan2
- DNAH5 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763771549, COSV54216174; called by muse, mutect2, varscan2
- DNAH7 | c.10156C>T p.R3386C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755753242, COSV56759604; called by muse, mutect2, varscan2
- DOCK9 | c.331G>A p.E111K (on ENST00000376460 / NM_001366676.2; = p.E112K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100240611; called by muse, mutect2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2
- DPYSL5 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs868412309, COSV56511352, COSV99982386; called by muse, varscan2
- DRC7 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV61054060; called by muse, mutect2, varscan2
- DRD2 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.388); catalogued as rs144999500, COSV60758565; called by mutect2, varscan2
- DSC3 | c.354G>A p.K118= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100844693; called by muse, mutect2, varscan2
- DSCAML1 | c.1285G>A p.E429K (on ENST00000321322; = p.E369K on NM_020693.4) | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs777606240, COSV58399468; called by muse, mutect2, varscan2
- DSP | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs759084237, COSV101131211, COSV65793314; called by mutect2, varscan2
- EDA | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV100999605; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs1272679401, COSV100201165; called by muse, mutect2, varscan2
- EFCAB6 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs1430669062, COSV99414152, COSV99414201; called by muse, mutect2
- EIF2D | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV99662982; called by muse, mutect2, varscan2
- ELF3 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100668901; called by muse, mutect2, varscan2
- ENOX1 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54889850, COSV99816830; called by muse, mutect2, varscan2
- EPHA10 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100361639; called by muse, mutect2
- EPHA6 | c.2728G>A p.D910N (on ENST00000389672 / NM_001080448.3; = p.D302N on NM_173655.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs887311559, COSV67572377; called by muse, mutect2
- EPHA7 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100994177; called by muse, mutect2
- EPHA7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.722); catalogued as rs1251015381, COSV100992487; called by muse, mutect2
- ERC2 | c.493C>G p.R165G | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99888305; called by muse, mutect2, varscan2
- ERICH3 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100445315; called by muse, mutect2, varscan2
- F13B | c.800G>C p.C267S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803395; called by muse, mutect2, varscan2
- FAM171A1 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs866736199, COSV100968441; called by muse, mutect2, varscan2
- FAM83B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV60922315; called by muse, mutect2, varscan2
- FAT1 | c.13100C>T p.S4367F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499475, COSV101499580; called by muse, mutect2, varscan2
- FBL | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs769879656, COSV99695390; called by muse, mutect2
- FBLN2 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV55485739; called by muse, mutect2
- FBN3 | c.2956+1G>A p.X986_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99561590; called by muse, mutect2, varscan2
- FBXO30 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485375136, COSV99395368; called by muse, mutect2, varscan2
- FCN1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65662457, COSV65662875; called by muse, mutect2, varscan2
- FCRL3 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63840285; called by muse, mutect2, varscan2
- FGD5 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV99548966; called by muse, mutect2, varscan2
- FGF23 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1206151319, COSV52977264; called by muse, mutect2, varscan2
- FKBP5 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374759584; called by muse, mutect2, varscan2
- FKBP9 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as COSV54234203; called by muse, mutect2, varscan2
- FLG | c.11462A>T p.D3821V | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100911976; called by muse, mutect2, varscan2
- FLG2 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV101166113, COSV66166433; called by muse, mutect2, varscan2
- FLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101165662; called by muse, mutect2, varscan2
- FLT3 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as rs559157798, COSV54050368; called by muse, mutect2, varscan2
- FRAS1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs917920184, COSV99355018; called by muse, mutect2, varscan2
- FZD6 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100708474; called by muse, mutect2, varscan2
- GAA | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100163455; called by muse, mutect2, varscan2
- GABRE | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as rs769356968, COSV100944284, COSV100944343; called by muse, mutect2, varscan2
- GBA3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs571805473, COSV101545494, COSV101545549; called by muse, mutect2, varscan2
- GDA | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs370557253; called by muse, mutect2, varscan2
- GFRA1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs865969043, COSV100815992; called by muse, mutect2, varscan2
- GIMAP1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100212028; called by muse, mutect2
- GLCE | c.553C>G p.R185G | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99962076, COSV99962568; called by muse, mutect2, varscan2
- GLIS3 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100174600; called by muse, mutect2, varscan2
- GLRB | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100030048; called by muse, mutect2
- GMDS | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs868623141, COSV66431278; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR42 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs750165933, COSV101497381; called by mutect2, varscan2
- GRID1 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100024504, COSV100025892; called by muse, mutect2, varscan2
- GRIK3 | c.255G>C p.R85S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as COSV100902243, COSV100902248; called by muse, mutect2, varscan2
- GRIK4 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101483702; called by muse, mutect2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRIN2A | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100409852, COSV58020198; called by muse, mutect2, varscan2
- GRIN2A | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100410721; called by muse, varscan2
- GRIN3A | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV100701722; called by muse, mutect2, varscan2
- GRK2 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs542501875, COSV57952361; called by muse, mutect2, varscan2
- GRM7 | c.2149G>A p.V717M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1248364429, COSV100737977; called by muse, mutect2, varscan2
- GSDMC | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52692853, COSV52695586; called by muse, mutect2, varscan2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2, varscan2
- GUCA1C | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs866753047, COSV99225116, COSV99227352; called by muse, mutect2, varscan2
- HCRTR2 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100904545; called by muse, mutect2, varscan2
- HDAC5 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99870900; called by muse, mutect2, varscan2
- HDAC5 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.331); catalogued as COSV99870901; called by muse, mutect2, varscan2
- HHLA2 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100755507; called by muse, mutect2, varscan2
- HK3 | c.1534C>T p.L512F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770309131, COSV99459143; called by muse, mutect2, varscan2
- HMCN1 | c.8729G>A p.G2910E | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99634119; called by muse, mutect2, varscan2
- HMGCR | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV55316166; called by muse, mutect2, varscan2
- HOATZ | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs367598611; called by muse, mutect2, varscan2
- HRC | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV53255853; called by muse, mutect2, varscan2
- IFI35 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs771605420, COSV99887927; called by muse, mutect2, varscan2
- IFIH1 | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV99718807; called by muse, mutect2, varscan2
- IGHV3-33 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.07); catalogued as rs771115508; called by muse, mutect2, varscan2
- IGLV4-60 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV101135248; called by muse, mutect2, varscan2
- IGSF10 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as COSV99192495; called by muse, mutect2
- IGSF9 | c.3209A>C p.H1070P (on ENST00000368094 / NM_001135050.2; = p.H1054P on NM_020789.4) | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.648); catalogued as COSV100231286; called by muse, mutect2, varscan2
- IGSF9B | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100318239; called by muse, mutect2
- IL21R | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV61969833; called by muse, mutect2, varscan2
- IL31RA | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100732846; called by muse, mutect2, varscan2
- INO80 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs771493839, COSV100732024, COSV62736306; called by muse, mutect2, varscan2
- INPP5K | c.569T>A p.F190Y | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100233883; called by muse, mutect2, varscan2
- ITGA8 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100959594; called by muse, mutect2, varscan2
- ITGAE | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99561263; called by muse, mutect2, varscan2
- ITGB3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101457658, COSV71383891; called by muse, mutect2, varscan2
- ITIH2 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100623378; called by muse, mutect2, varscan2
- ITPRIP | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.092); catalogued as COSV99532681; called by muse, mutect2, varscan2
- JCAD | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV100948525; called by muse, mutect2, varscan2
- KBTBD12 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV100675495; called by muse, mutect2, varscan2
- KCNC1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200015927, COSV56393147; called by muse, mutect2, varscan2
- KCNJ3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1214174573, COSV54534893, COSV54540893; called by muse, mutect2, varscan2
- KCNK3 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100257098; called by muse, mutect2, varscan2
- KCNN3 | c.2189G>T p.G730V (on ENST00000618040 / NM_001204087.1; = p.G715V on NM_002249.6) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99679020; called by muse, mutect2, varscan2
- KCTD16 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV101568680; called by muse, mutect2, varscan2
- KIAA0319 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65501509; called by muse, mutect2, varscan2
- KIF17 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as rs367672816, COSV56117515; called by muse, mutect2, varscan2
- KIF23 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV99532620; called by muse, mutect2, varscan2
- KIF2B | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.368); catalogued as COSV52131041; called by muse, mutect2, varscan2
- KIRREL2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV52879647; called by muse, mutect2, varscan2
- KL | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66309156; called by muse, mutect2, varscan2
- KLC1 | c.492C>T p.S164= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs754322654, COSV99870986, COSV99871781; called by muse, mutect2, varscan2
- KLHDC10 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100111018; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KLHDC8A | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.992); catalogued as COSV100903868; called by muse, mutect2, varscan2
- KLHL4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100910089, COSV64145236; called by muse, mutect2, varscan2
- KLK15 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763136204, COSV100033077, COSV56826089; called by muse, mutect2, varscan2
- KLK8 | c.231G>A p.P77= | Splice Region (SNP) | VAF 21/116 reads (18%) | catalogued as COSV51590657; called by muse, mutect2, varscan2
- KNOP1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV99575320; called by muse, mutect2, varscan2
- KRBA1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs748833690, COSV99753017; called by muse, mutect2, varscan2
- LAD1 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100943920; called by muse, mutect2, varscan2
- LAMA1 | c.3986G>A p.G1329E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.907); catalogued as rs748965785, COSV101057398; called by muse, mutect2, varscan2
- LILRB2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs576220286, COSV100079010; called by muse, mutect2, varscan2
- LIN7A | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs772890581, COSV54019429; called by muse, mutect2
- LONP1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759923141, COSV62263288; called by muse, mutect2, varscan2
- LPAR4 | c.749T>G p.M250R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101425153; called by muse, mutect2, varscan2
- LRFN5 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99985037; called by muse, mutect2, varscan2
- LRP1B | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67184445, COSV67241706; called by muse, mutect2, varscan2
- LRP5 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348763555, COSV99592510; called by muse, mutect2, varscan2
- LRRC37A3 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs374690010; called by muse, mutect2, varscan2
- LTF | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 66/205 reads (32%) | catalogued as COSV99210730; called by muse, mutect2, varscan2
- MAPK12 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99299596; called by muse, mutect2, varscan2
- MAPT | c.1135C>T p.H379Y (on ENST00000262410 / NM_001377265.1; = p.H304Y on NM_016835.4) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1213524576, COSV99291158, COSV99291236; called by muse, mutect2
- MBD5 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101290229; called by mutect2, varscan2
- MCTP1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV100387877; called by muse, mutect2, varscan2
- MED23 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866726564, COSV100645308; called by muse, varscan2
- MEGF6 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99621128; called by muse, mutect2
- METTL1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760403195, COSV99141632; called by muse, mutect2, varscan2
- METTL24 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV100133563; called by muse, mutect2, varscan2
- MGAM | c.3318G>A p.W1106* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV101527702; called by muse, mutect2
- MGAM | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs1257913428, COSV101527703; called by muse, mutect2
- MIOX | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99327055; called by muse, mutect2, varscan2
- MITD1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs373110802; called by muse, mutect2, varscan2
- MLIP | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV99228231, COSV99230214, COSV99230369; called by muse, mutect2
- MMP1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as rs1469324107, COSV100188057; called by muse, mutect2, varscan2
- MMP13 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52823154; called by muse, mutect2, varscan2
- MRGPRX1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57106316; called by muse, mutect2, varscan2
- MRGPRX2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100316822; called by muse, mutect2, varscan2
- MS4A6E | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752908828, COSV55726872; called by muse, mutect2, varscan2
- MS4A8 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100282611; called by muse, mutect2, varscan2
- MTCH2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100207086; called by muse, mutect2, varscan2
- MUC16 | c.41575G>A p.D13859N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as COSV101110034, COSV66694513; called by muse, mutect2, varscan2
- MUC16 | c.28621G>A p.E9541K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV101200994; called by muse, mutect2
- MUC16 | c.28229C>T p.T9410I | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.207); catalogued as COSV101200998; called by muse, mutect2
- MUC16 | c.22328C>T p.P7443L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV101201000, COSV67476720; called by muse, mutect2, varscan2
- MUC16 | c.13451C>T p.S4484L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs866646168, COSV101201002; called by muse, mutect2, varscan2
- MUC16 | c.10469C>T p.S3490F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV101201003; called by muse, mutect2, varscan2
- MUC17 | c.9308G>A p.G3103E | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs745457096, COSV100074687; called by muse, mutect2, varscan2
- MUC17 | c.11567C>T p.S3856F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1478221727, COSV60287087; called by muse, mutect2, varscan2
- MXRA5 | c.5948C>T p.S1983F | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277492063, COSV54239198; called by muse, mutect2, varscan2
- MYH1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56845725; called by muse, mutect2, varscan2
- MYH2 | c.3928G>A p.G1310S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV99820212; called by muse, mutect2, varscan2
- MYL2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57406359, COSV99960858; called by muse, varscan2
- MYO15A | c.6095G>A p.R2032Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs144054368, COSV52763951; called by muse, mutect2
- MYO3B | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529027538, COSV58693153; called by muse, mutect2, varscan2
- MYOCD | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV58499880; called by muse, mutect2, varscan2
- MYOM2 | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186595396, COSV50730015; called by muse, mutect2, varscan2
- MYPN | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs749334556, COSV100590437; called by muse, mutect2, varscan2
- N4BP2 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99789129; called by muse, mutect2, varscan2
- NACA2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101478569; called by muse, mutect2, varscan2
- NBEAL1 | c.6442C>T p.P2148S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV68917170; called by muse, mutect2, varscan2
- NBEAL2 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as COSV99435192, COSV99437214; called by muse, mutect2, varscan2
- NDST4 | c.121A>T p.M41L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99997501, COSV99998224; called by muse, mutect2, varscan2
- NEK9 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99464428; called by muse, mutect2, varscan2
- NELL2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100421185, COSV61569528; called by muse, varscan2
- NELL2 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs754660490, COSV61575247; called by muse, mutect2
- NFATC4 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99149825; called by muse, mutect2, varscan2
- NLRP5 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101173316, COSV66767529; called by muse, mutect2, varscan2
- NME8 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs766019144, COSV52256987; called by mutect2, varscan2
- NME8 | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV99553719; called by mutect2, varscan2
- NMNAT3 | c.511G>A p.D171N (on ENST00000296202 / NM_001320512.1; = p.D134N on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.119); catalogued as rs375842109; called by muse, mutect2, varscan2
- NOL4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99307948; called by muse, mutect2, varscan2
- NOS1 | c.3767C>T p.T1256I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501211; called by muse, mutect2, varscan2
- NR1H3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101269798; called by muse, mutect2, varscan2
- NRG1 | c.236C>T p.S79F (on ENST00000523534; = p.S226F on NM_013962.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101585046; called by muse, mutect2, varscan2
- NRXN3 | c.1859G>A p.S620N (on ENST00000335750 / NM_001330195.2; = p.S247N on NM_004796.6) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1025247872, COSV100207529; called by muse, mutect2, varscan2
- OGDHL | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100934466; called by muse, mutect2, varscan2
- OR10J1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71129568; called by muse, mutect2, varscan2
- OR10S1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs146618461; called by muse, mutect2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, mutect2, varscan2
- OR1B1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs761446363, COSV100506523; called by muse, mutect2, varscan2
- OR1L1 | c.931C>T p.Q311* (on ENST00000373686; = p.Q261* on NM_001005236.3) | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV100542178; called by muse, mutect2, varscan2
- OR2A25 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV68717067; called by muse, mutect2, varscan2
- OR2B2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.412); catalogued as COSV100308209; called by muse, mutect2, varscan2
- OR2C3 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100825765; called by muse, mutect2, varscan2
- OR2T3 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV62083348, COSV62084077; called by muse, mutect2, varscan2
- OR2T8 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100178428; called by muse, mutect2, varscan2
- OR2Z1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV60693334; called by muse, mutect2, varscan2
- OR3A1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60162707; called by muse, mutect2, varscan2
- OR4C6 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV58602760; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR4F15 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1460634616, COSV100173937; called by muse, mutect2, varscan2
- OR51A7 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs865781043, COSV100834732; called by muse, varscan2
- OR51T1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200553277, COSV100434335, COSV59024390; called by muse, mutect2
- OR52E2 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs141829103; called by muse, mutect2, varscan2
- OR5T3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.314); catalogued as rs267602998, COSV100282930; called by muse, mutect2, varscan2
- OR7G1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1223651049, COSV53318893, COSV53319270; called by muse, mutect2, varscan2
- OR8A1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as rs867517993, COSV99420786; called by muse, mutect2, varscan2
- OR8H2 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV57947212; called by muse, mutect2, varscan2
- OR8H3 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100539123; called by muse, mutect2
- OTOF | c.1206G>A p.G402= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99716249, COSV99718640; called by muse, mutect2, varscan2
- OTULINL | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV57034226; called by muse, mutect2, varscan2
- P3H2 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV60020194; called by muse, mutect2, varscan2
- PARP8 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as COSV99892451; called by muse, mutect2, varscan2
- PASK | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99300076; called by muse, mutect2, varscan2
- PCDHAC1 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53838602, COSV53862217; called by muse, mutect2, varscan2
- PCDHB10 | c.2014C>G p.P672A | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV99504846; called by muse, mutect2, varscan2
- PCDHGA6 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs757227553, COSV99544486; called by muse, mutect2, varscan2
- PCDHGB5 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs368407532, COSV53973969; called by mutect2, varscan2
- PCLO | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV100436374; called by muse, mutect2
- PCLO | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.088); catalogued as COSV61640377; called by muse, mutect2, varscan2
- PDE10A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV100605542; called by muse, mutect2
- PDE1C | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs550592420, COSV58503459; called by muse, mutect2, varscan2
- PDLIM5 | c.320T>G p.V107G | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100524230; called by muse, mutect2, varscan2
- PDZD2 | c.3212G>A p.G1071E | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV56854562, COSV99226249; called by muse, mutect2, varscan2
- PDZRN4 | c.1678G>A p.E560K (on ENST00000402685 / NM_001164595.2; = p.E302K on NM_013377.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54206912, COSV54207966; called by muse, mutect2, varscan2
- PGC | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63122426; called by muse, mutect2, varscan2
- PHC3 | c.2212G>A p.D738N (on ENST00000494943 / NM_001308116.2; = p.D750N on NM_024947.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101520183; called by muse, mutect2, varscan2
- PIK3CA | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55994293, COSV99842018; called by muse, mutect2, varscan2
- PIK3CG | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.718); catalogued as rs755134917, COSV63247006; called by muse, mutect2, varscan2
- PIKFYVE | c.567T>G p.S189R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100011277; called by muse, mutect2, varscan2
- PIP5K1A | c.1411C>T p.R471W (on ENST00000368888 / NM_001135638.2; = p.R458W on NM_003557.3) | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); catalogued as rs1360030623, COSV62957228; called by muse, mutect2, varscan2
- PKD2L1 | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100559427; called by muse, mutect2, varscan2
- PLBD1 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs1160084923, COSV99554760; called by muse, mutect2, varscan2
- PLEKHA4 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1450546419, COSV54362880; called by muse, mutect2, varscan2
- PLEKHM3 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101216806; called by muse, mutect2, varscan2
- PLG | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV51985439, COSV51986146; called by muse, mutect2, varscan2
- PLPP4 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100956526, COSV64829518; called by muse, mutect2, varscan2
- PLXND1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60718595; called by muse, mutect2, varscan2
- POFUT2 | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215501669, COSV100499379; called by muse, mutect2
- POLR2F | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV101328964; called by muse, mutect2
- PRAMEF10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201689660; called by muse, mutect2, varscan2
- PRB2 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV66984215, COSV66984501; called by muse, varscan2
- PRKCZ | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1011618567, COSV101058052; called by muse, mutect2, varscan2
- PROSER1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV100612981; called by muse, mutect2
- PROX1 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99800041; called by muse, mutect2, varscan2
- PRR27 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs766217684, COSV100748870, COSV60641441; called by muse, mutect2, varscan2
- PSG11 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100106066; called by muse, mutect2, varscan2
- PSG11 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768654374, COSV60454253; called by muse, mutect2, varscan2
- PTN | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100780993; called by muse, mutect2, varscan2
- PTPRB | c.4744C>T p.R1582* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs745519352, COSV54249559; called by muse, mutect2
- PTPRK | c.4025G>A p.R1342Q (on ENST00000368215 / NM_001291984.2; = p.R1343Q on NM_002844.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs754669062, COSV63890691; called by muse, mutect2, varscan2
- PTPRN2 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV67052509; called by muse, mutect2, varscan2
- PTPRR | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs866393565, COSV51748930, COSV99317061; called by muse, mutect2
- RAB27B | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs753780291, COSV50494748; called by muse, mutect2, varscan2
- RAD51AP2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV101208396; called by muse, mutect2, varscan2
- RAG1 | c.68T>A p.I23N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV100201089; called by muse, mutect2, varscan2
- RAI1 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs149164900; called by muse, mutect2, varscan2
- RALGPS1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99402360; called by muse, mutect2, varscan2
- RARRES2 | c.282G>A p.R94= | Splice Region (SNP) | VAF 32/94 reads (34%) | catalogued as COSV56231610; called by muse, mutect2, varscan2
- RASGRP4 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV99385153; called by muse, mutect2
- RBBP6 | c.4705C>T p.R1569C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs191159591, COSV100154517; called by muse, mutect2, varscan2
- RBM10 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV61307730; called by muse, mutect2
- RELA | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.154); catalogued as rs201037601, COSV100425911; called by muse, mutect2, varscan2
- RGL3 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66510274; called by muse, mutect2, varscan2
- RGL3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs768967060, COSV100993086; called by muse, mutect2, varscan2
- RGS9 | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99287877; called by muse, mutect2, varscan2
- RHOH | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101110591; called by muse, mutect2, varscan2
- RNF214 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1009188753, COSV100326893; called by muse, varscan2
- RNF31 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99396244; called by muse, mutect2, varscan2
- RP1 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs868697369, COSV55117337, COSV55125832; called by muse, mutect2, varscan2
- RPF2 | c.741G>A p.K247= | Splice Region (SNP) | VAF 11/47 reads (23%) | catalogued as rs867185560, COSV100923334; called by muse, mutect2, varscan2
- RPL5 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs764649729, COSV59873485; called by muse, mutect2, varscan2
- RPTN | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100285683; called by muse, mutect2, varscan2
- RSPH6A | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.438); catalogued as rs1183130472, COSV99537366; called by muse, varscan2
- RSPH6A | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV55574773; called by muse, mutect2, varscan2
- SAGE1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100187738; called by muse, mutect2, varscan2
- SALL3 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs765703425, COSV101610039; called by muse, mutect2, varscan2
- SALL3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV73305823; called by muse, mutect2, varscan2
- SCAPER | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1013743089, COSV100239218; called by muse, mutect2, varscan2
- SCFD1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV100356512; called by muse, mutect2, varscan2
- SCN10A | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV101479499; called by muse, mutect2, varscan2
- SCN10A | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101479500; called by muse, mutect2, varscan2
- SCN3A | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759649419, COSV51803430; called by muse, mutect2, varscan2
- SEMA3E | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs145707650, COSV100319578, COSV57108396; called by muse, mutect2, varscan2
- SEMA3E | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1049236480, COSV100317149; called by muse, mutect2, varscan2
- SEMA4A | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61772245; called by muse, mutect2, varscan2
- SERPINB2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV55093105; called by muse, mutect2, varscan2
- SERPINB7 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.357); catalogued as COSV100320990; called by muse, mutect2, varscan2
- SERPINI2 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV52988161, COSV99248278; called by muse, mutect2
- SERTM1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100171468; called by muse, mutect2, varscan2
- SGMS1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV100693634; called by muse, mutect2, varscan2
- SI | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs1347233015, COSV52264647, COSV52301779; called by muse, mutect2, varscan2
- SIGLEC10 | c.1046T>G p.V349G | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100219339; called by muse, mutect2, varscan2
- SIPA1L1 | c.4385C>T p.S1462F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100665912; called by muse, mutect2, varscan2
- SIPA1L3 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV99730079; called by muse, mutect2, varscan2
- SLC12A3 | c.2666G>A p.G889E (on ENST00000563236 / NM_001126108.2; = p.G898E on NM_000339.3) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as rs757238656, COSV52632355; called by muse, mutect2, varscan2
- SLC17A1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV99766031; called by muse, mutect2, varscan2
- SLC17A4 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100930612, COSV100930656; called by muse, mutect2, varscan2
- SLC19A2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52546948, COSV99357097; called by muse, mutect2, varscan2
- SLC22A14 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99828324; called by muse, mutect2, varscan2
- SLC27A2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV51059548; called by muse, mutect2, varscan2
- SLC5A8 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as rs778188770, COSV73311323; called by muse, mutect2, varscan2
- SLC6A1 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99823113; called by muse, mutect2, varscan2
- SLC6A1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99823116; called by muse, mutect2, varscan2
- SLC8A1 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.635); catalogued as COSV100247126; called by muse, mutect2, varscan2
- SLC9A2 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866482607, COSV52130900; called by muse, mutect2, varscan2
- SLIT1 | c.3772G>A p.V1258M | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs764610984, COSV99820517; called by muse, mutect2, varscan2
- SMS | c.113C>G p.S38W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV101048253; called by muse, mutect2, varscan2
- SNCB | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100031357; called by muse, mutect2
- SNRNP40 | c.771T>A p.N257K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV99745607; called by mutect2, varscan2
- SNTB2 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293352; called by muse, mutect2, varscan2
- SORCS3 | c.3376G>A p.A1126T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100865547; called by muse, mutect2, varscan2
- SP140 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1202851194, COSV100613980; called by muse, mutect2, varscan2
- SPANXD | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV65152354; called by muse, mutect2, varscan2
- SPATA5L1 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99973288; called by muse, mutect2, varscan2
- SPHKAP | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100764437, COSV60893199; called by muse, mutect2, varscan2
- SPINK5 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV56258034; called by muse, mutect2, varscan2
- SPTBN1 | c.5743C>T p.R1915C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287979528, COSV61690331; called by muse, mutect2, varscan2
- SRPX2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100884055; called by muse, mutect2
- SSH2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99282781; called by muse, mutect2, varscan2
- SSH2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52175326; called by muse, mutect2, varscan2
- ST18 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.794); catalogued as COSV99390740; called by muse, mutect2, varscan2
- ST8SIA2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 23/120 reads (19%) | PolyPhen possibly damaging (0.719); catalogued as COSV99184496; called by muse, mutect2, varscan2
- ST8SIA4 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99185450; called by muse, mutect2, varscan2
- STK31 | c.1596G>A p.K532= | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100669654; called by muse, mutect2, varscan2
- STXBP2 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769717341, CM096293, COSV55405510; called by muse, mutect2, varscan2
- STXBP5L | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757487745, COSV56519058; called by muse, mutect2, varscan2
- SULT1A2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100187321; called by muse, mutect2, varscan2
- SUPT16H | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99360133; called by muse, mutect2, varscan2
- SV2C | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs780371830, COSV100456661; called by muse, mutect2, varscan2
- SYT9 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV100608901; called by muse, mutect2, varscan2
- SZT2 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100987585; called by muse, mutect2
- SZT2 | c.6694C>T p.P2232S (on ENST00000634258 / NM_001365999.1; = p.P2175S on NM_015284.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100987586; called by muse, mutect2, varscan2
- TAAR5 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99236975; called by muse, mutect2, varscan2
- TAS2R8 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.345); catalogued as COSV104383552, COSV99553919; called by muse, mutect2, varscan2
- TBX15 | c.1126C>T p.H376Y (on ENST00000369429 / NM_001330677.2; = p.H270Y on NM_152380.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV52870399; called by muse, mutect2
- TCEANC2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); catalogued as COSV99328790; called by muse, mutect2, varscan2
- TENM2 | c.2399G>A p.R800K (on ENST00000518659 / NM_001122679.2; = p.R568K on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101319358; called by muse, mutect2
- TEX15 | c.1915G>A p.V639I (on ENST00000256246; = p.V1022I on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV99821929; called by muse, mutect2, varscan2
- TF | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs758892553, COSV99396283; called by muse, mutect2, varscan2
- TG | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200687678, COSV99602604; called by muse, mutect2, varscan2
- THBS2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64677115, COSV64682948; called by muse, mutect2, varscan2
- THSD7A | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1213861708, COSV70264819, COSV70264976; called by muse, mutect2, varscan2
- THYN1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99844026, COSV99844515; called by muse, mutect2, varscan2
- TIAM2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100019823; called by muse, mutect2, varscan2
- TJP3 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs375489474, COSV53663262; called by muse, mutect2, varscan2
- TLL1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99288636; called by mutect2, varscan2
- TMC5 | c.2068G>A p.E690K (on ENST00000396229 / NM_001105248.1; = p.E444K on NM_024780.5) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201778492, COSV54900449; called by muse, mutect2, varscan2
- TMCC3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs374305237, COSV54155538; called by muse, mutect2, varscan2
- TMEM132B | c.1467G>A p.M489I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV100170016; called by muse, mutect2, varscan2
- TMEM184A | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1306858670, COSV99868692; called by muse, mutect2, varscan2
- TMEM200A | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51648640, COSV51660625; called by muse, mutect2, varscan2
- TMEM252 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101051147; called by muse, mutect2, varscan2
- TMPRSS11F | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100678518, COSV100678738; called by muse, mutect2, varscan2
- TNS1 | c.4641C>T p.F1547= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as rs141774958; called by muse, mutect2, varscan2
- TP53BP1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55508074; called by muse, mutect2, varscan2
- TP63 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1173679499, COSV53196685; called by mutect2, varscan2
- TPRG1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV61463642; called by muse, mutect2, varscan2
- TRAV1-2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs777942817; called by muse, mutect2, varscan2
- TRBV6-1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1021645630; called by muse, mutect2, varscan2
- TRIM29 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1226994653, COSV59280583; called by muse, mutect2, varscan2
- TRIM43 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs543946833, COSV99720043; called by muse, mutect2, varscan2
- TRIM46 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV100104737; called by muse, mutect2, varscan2
- TRIM59 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100557496; called by muse, mutect2, varscan2
- TRIP11 | c.5773C>T p.P1925S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1451731175, COSV99971054; called by muse, mutect2, varscan2
- TRPM4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs750176955, COSV99420688; called by muse, mutect2, varscan2
- TRPV2 | c.1656C>T p.A552= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100641335; called by muse, mutect2, varscan2
- TRPV4 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99924982; called by muse, mutect2, varscan2
- TSHZ2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.121); catalogued as rs149724132; called by muse, mutect2, varscan2
- TSPYL2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.219); catalogued as COSV100212397; called by muse, mutect2, varscan2
- TTN | c.76018C>T p.R25340W (on ENST00000591111; = p.R17916W on NM_003319.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | PolyPhen possibly damaging (0.689); catalogued as rs779878975, COSV59881684; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.49336G>A p.D16446N (on ENST00000591111; = p.D9022N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV100625416; called by muse, mutect2, varscan2
- TTN | c.34960G>A p.E11654K (on ENST00000591111; = p.E10727K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | PolyPhen benign (0); catalogued as COSV60349505, COSV99045995; called by muse, mutect2, varscan2
- TTN | c.10646A>G p.Y3549C (on ENST00000591111; = p.Y3503C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs936605126, COSV100625420; called by muse, mutect2, varscan2
- UACA | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.355); catalogued as rs1349863148, COSV100537671; called by muse, mutect2
- UBE2J2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100231240; called by muse, mutect2, varscan2
- UNC119B | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753313005, COSV60865983; called by muse, mutect2, varscan2
- USH2A | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs375741757; called by mutect2, varscan2
- USP17L2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs766015132, COSV100414696; called by mutect2, varscan2
- USP48 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV100380179; called by muse, mutect2
- USP6 | c.2362G>A p.G788R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.937); catalogued as rs768733961, COSV100004695, COSV51485738; called by muse, mutect2, varscan2
- UTRN | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100840204, COSV100840312; called by mutect2, varscan2
- VDAC3 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV50081381, COSV99195137; called by muse, mutect2, varscan2
- VIT | c.1900G>A p.E634K (on ENST00000389975 / NM_001177969.1; = p.E649K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs747748359, COSV64899179; called by muse, varscan2
- VWC2L | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as COSV100436211; called by muse, varscan2
- WDR20 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100085386; called by muse, mutect2, varscan2
- WDR3 | c.941T>A p.I314N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV100832322; called by muse, mutect2, varscan2
- XDH | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as COSV101052429; called by muse, mutect2, varscan2
- XIRP2 | c.9620G>A p.G3207E (on ENST00000628543; = p.G3382E on NM_152381.6) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99746289; called by muse, mutect2, varscan2
- ZAN | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs371241253, COSV61807204; called by muse, mutect2, varscan2
- ZC2HC1A | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV99804362; called by muse, mutect2, varscan2
- ZFHX4 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.666); catalogued as rs575428085, COSV99266405; called by muse, mutect2, varscan2
- ZFYVE9 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV55090930; called by muse, mutect2, varscan2
- ZG16B | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV66526051; called by muse, mutect2, varscan2
- ZIM3 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV54143187, COSV99518481; called by muse, mutect2, varscan2
- ZNF239 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.862); catalogued as COSV100021879; called by muse, mutect2, varscan2
- ZNF277 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs1466090528, COSV100702521; called by muse, mutect2, varscan2
- ZNF395 | c.1520C>A p.A507D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100734051, COSV100734056; called by muse, mutect2, varscan2
- ZNF429 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.11); catalogued as rs368617365; called by muse, mutect2, varscan2
- ZNF479 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58643190; called by muse, mutect2, varscan2
- ZNF514 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99727915; called by muse, mutect2, varscan2
- ZNF551 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs1373751315, COSV56594299; called by muse, mutect2, varscan2
- ZNF556 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs887666848, COSV56912642; called by muse, mutect2, varscan2
- ZNF560 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.081); catalogued as COSV100038929, COSV56868544; called by muse, mutect2, varscan2
- ZNF613 | c.812G>A p.W271* (on ENST00000293471 / NM_001031721.4; = p.W235* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs531481311, COSV99523030; called by muse, mutect2, varscan2
- ZNF613 | c.813G>A p.W271* (on ENST00000293471 / NM_001031721.4; = p.W235* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99523031; called by muse, mutect2, varscan2
- ZNF630 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99332532; called by muse, mutect2, varscan2
- ZNF667 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410847; called by muse, mutect2, varscan2
- ZNF692 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV100133913; called by muse, mutect2
- ZNF831 | c.4450C>T p.H1484Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as COSV100926194; called by muse, mutect2, varscan2
- ANKRD11 | c.806_808delinsTG p.T269Mfs*3 | Frame Shift Del (DEL) | VAF 23/150 reads (15%) | called by pindel, varscan2*
- ARFGEF3 | c.5873A>T p.K1958I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ELOA3B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FADS1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, varscan2
- IL32 | c.373G>A p.G125R (on ENST00000396890 / NM_001308078.4; = p.G79R on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13D | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCD2 | c.2076C>T p.I692= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100429723; called by muse, mutect2, varscan2
- ACAP2 | c.2127C>T p.D709= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100462585; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1152C>T p.F384= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV56473968; called by muse, mutect2, varscan2
- ADAMTS18 | c.642C>T p.Y214= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs1326757975, COSV51398598, COSV51403695; called by muse, mutect2, varscan2
- ADAMTS20 | c.4050G>A p.E1350= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101166375; called by muse, mutect2
- ADCY10 | c.3159C>T p.I1053= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1411373695, COSV63241116; called by muse, mutect2, varscan2
- ADRB2 | c.774C>T p.L258= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs555275446, COSV100019301; called by muse, mutect2, varscan2
- AHNAK | c.7344C>T p.F2448= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV99949009; called by muse, mutect2, varscan2
- AHRR | c.1407G>A p.R469= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100327852; called by muse, mutect2, varscan2
- ANO4 | c.1731G>A p.T577= (on ENST00000392977 / NM_001286615.2; = p.T542= on NM_178826.4) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs752244271, COSV100153598, COSV54583713; called by muse, mutect2, varscan2
- ARHGAP36 | c.1515C>T p.S505= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs375497123, COSV52269551; called by muse, mutect2, varscan2
- ARID2 | c.4083C>T p.I1361= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100536769; called by muse, mutect2, varscan2
- ARMC6 | c.1353C>T p.P451= (on ENST00000392336; = p.P426= on NM_033415.4) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99523141; called by muse, mutect2, varscan2
- ARSA | c.1341G>C p.V447= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99332469; called by muse, mutect2, varscan2
- ASB16 | c.471C>T p.D157= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99519025; called by muse, mutect2, varscan2
- ASCC2 | c.501C>T p.L167= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100316439; called by muse, mutect2, varscan2
- ATM | c.4855A>C p.R1619= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99591277; called by muse, mutect2, varscan2
- ATP13A4 | c.2628C>T p.F876= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV61320157; called by muse, mutect2, varscan2
- ATP13A5 | c.2787C>T p.L929= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100665574, COSV60874884; called by muse, mutect2, varscan2
- ATP1A2 | c.2685G>A p.L895= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100768097; called by muse, mutect2, varscan2
- ATP1A3 | c.2985C>T p.F995= (on ENST00000545399 / NM_001256214.2; = p.F982= on NM_152296.5) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs182309368, COSV57485691; called by muse, mutect2, varscan2
- ATRAID | c.609C>T p.I203= (on ENST00000611786; = p.I90= on NM_016085.5) | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV99255541; called by muse, mutect2, varscan2
- ATXN1 | c.381C>T p.F127= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1410967835, COSV99787399; called by muse, mutect2, varscan2
- BAG6 | c.3048C>T p.A1016= (on ENST00000676571; = p.A969= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1228056981, COSV99277488; called by muse, mutect2, varscan2
- BDKRB1 | c.1029G>A p.R343= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs373631625, COSV53706618; called by muse, mutect2, varscan2
- BDKRB2 | c.441C>T p.F147= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs748411805, COSV100021387; called by muse, mutect2, varscan2
- BIN1 | c.621G>A p.E207= (on ENST00000316724 / NM_001320642.1; = p.E176= on NM_004305.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99388398; called by muse, mutect2, varscan2
- BRAF | c.1035C>T p.P345= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1443155060, COSV99967475; called by muse, mutect2, varscan2
- BRINP2 | c.873G>A p.K291= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100838292; called by muse, mutect2, varscan2
- C9orf152 | c.453C>T p.L151= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as COSV101272399; called by muse, mutect2, varscan2
- CACNA1E | c.5823C>T p.L1941= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100704593; called by muse, mutect2, varscan2
- CAMK2G | c.1143C>T p.S381= (on ENST00000423381 / NM_001367518.1; = p.S347= on NM_001222.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99990171; called by muse, mutect2, varscan2
- CATIP | c.162C>T p.A54= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99179616; called by muse, mutect2
- CCDC157 | c.570C>T p.I190= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100199828; called by muse, mutect2, varscan2
- CCDC185 | c.1368C>T p.F456= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100838826, COSV64820159; called by muse, mutect2, varscan2
- CCDC88C | c.2628G>A p.L876= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV101106047; called by muse, mutect2, varscan2
- CDH22 | c.1050C>T p.S350= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs760860598, COSV100952962; called by muse, mutect2, varscan2
- CDH23 | c.7416C>T p.I2472= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99823137; called by muse, mutect2
- CDH6 | c.1839G>A p.T613= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs571410704, COSV54073791, COSV54077831; called by muse, mutect2, varscan2
- CECR2 | c.375G>T p.L125= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99378842; called by muse, mutect2, varscan2
- CES1 | c.1017G>A p.R339= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV62090142; called by muse, mutect2, varscan2
- CFH | c.2070C>A p.T690= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs778710774, COSV100809995, COSV100810238; called by muse, mutect2, varscan2
- CHAF1A | c.975C>T p.F325= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs143106881; called by muse, mutect2, varscan2
- CHRNA5 | c.768C>T p.F256= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs1331829287, COSV55140440; called by muse, mutect2, varscan2
- CLCN6 | c.1641C>T p.S547= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100412139; called by muse, mutect2, varscan2
- CLEC4M | c.315G>A p.E105= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs1178414841, COSV99940779; called by muse, mutect2, varscan2
- CLTCL1 | c.3087C>T p.I1029= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99595695; called by muse, mutect2, varscan2
- CLVS1 | c.366G>A p.L122= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV57975240; called by muse, mutect2, varscan2
- CNTNAP1 | c.3916C>T p.L1306= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV99226872; called by muse, mutect2, varscan2
- COL12A1 | c.7641C>T p.F2547= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs767944355, COSV100486350; called by muse, mutect2, varscan2
- COL20A1 | c.1818G>C p.G606= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100491225; called by muse, mutect2
- CPA1 | c.435G>A p.K145= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99163332; called by muse, mutect2, varscan2
- CRKL | c.498G>A p.K166= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1174088385, COSV100574191; called by muse, mutect2, varscan2
- CSAD | c.1047G>A p.T349= (on ENST00000444623 / NM_001244705.2; = p.T376= on NM_015989.5) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs138712396, COSV57243257; called by muse, mutect2, varscan2
- CSMD2 | c.6639C>T p.T2213= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs764029855, COSV99593974; called by mutect2, varscan2
- CTNNA3 | c.2154C>T p.F718= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV101041208, COSV65526612; called by muse, mutect2, varscan2
- CUL9 | c.1518C>T p.I506= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV99056032, COSV99335863; called by muse, mutect2, varscan2
- CYP24A1 | c.714C>T p.F238= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV53774073, COSV99398535; called by muse, mutect2, varscan2
- DAG1 | c.510C>T p.A170= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs147153370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKI | c.2667G>A p.R889= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99936662; called by muse, mutect2, varscan2
- DLD | c.792C>T p.I264= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99227423; called by muse, mutect2, varscan2
- DMBT1 | c.6438G>A p.G2146= (on ENST00000338354 / NM_001377530.1; = p.G1389= on NM_004406.3) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100353897; called by muse, mutect2, varscan2
- DNAH8 | c.8958G>A p.L2986= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100546764, COSV100546838, COSV59425223; called by muse, mutect2, varscan2
- DNER | c.1038C>T p.F346= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV59160738; called by muse, mutect2, varscan2
- DOCK4 | c.4821C>T p.S1607= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1241632422, COSV101447943; called by muse, mutect2, varscan2
- DOK4 | c.936G>A p.K312= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99538437; called by muse, mutect2
- DPPA2 | c.258G>A p.P86= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs753042582, COSV72117922; called by muse, mutect2
- DSG4 | c.273G>A p.G91= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV57389276; called by muse, mutect2, varscan2
- ECI2 | c.6G>A p.A2= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100326696; called by muse, mutect2
- EFCAB3 | c.1110C>T p.S370= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs762926000, COSV100540413, COSV59505942; called by muse, mutect2, varscan2
- EGFLAM | c.2019C>T p.F673= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as COSV100380633; called by muse, mutect2, varscan2
- EPHA3 | c.456C>T p.F152= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100345999; called by muse, mutect2, varscan2
- ERG | c.1038C>T p.F346= (on ENST00000398919 / NM_001243428.1; = p.F322= on NM_004449.4) | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99902565; called by muse, mutect2, varscan2
- EXT1 | c.1179C>T p.I393= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100984117; called by muse, mutect2, varscan2
- F10 | c.630C>T p.P210= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs897179923, COSV100979300; called by muse, mutect2, varscan2
- F2RL2 | c.852C>T p.A284= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99167869; called by muse, mutect2, varscan2
- F2RL3 | c.696G>C p.L232= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99935388; called by muse, varscan2
- F5 | c.186G>A p.K62= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100889205; called by muse, mutect2, varscan2
- FAT3 | c.10818C>T p.I3606= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as rs758422449, COSV53172463; called by muse, mutect2, varscan2
- FAT4 | c.13737G>A p.G4579= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV58683751; called by muse, mutect2, varscan2
- FCRL5 | c.2347C>T p.L783= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100709233, COSV62520524; called by muse, mutect2, varscan2
- FLT3LG | c.135C>T p.I45= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs745405068, COSV52619627; called by muse, mutect2, varscan2
- GALNT13 | c.831G>A p.R277= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV67223380; called by muse, mutect2, varscan2
- GJA10 | c.327G>A p.R109= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1329815734, COSV65354950; called by muse, mutect2, varscan2
- GLYAT | c.354T>C p.L118= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99557499; called by muse, mutect2, varscan2
- GNA13 | c.976C>T p.L326= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV101457499; called by muse, mutect2, varscan2
- GOLGA5 | c.2082C>T p.Y694= | Silent (SNP) | VAF 33/221 reads (15%) | catalogued as rs1267437836, COSV99371168; called by muse, mutect2, varscan2
- GRIN2A | c.2670C>T p.S890= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs764394577, COSV58045512; called by muse, varscan2
- GRIN2B | c.3219C>T p.I1073= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs376935636, COSV74205342; called by muse, mutect2, varscan2
- GSTA2 | c.249G>A p.G83= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as COSV101534069; called by muse, mutect2, varscan2
- GUCA1C | c.519C>T p.F173= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1028693252, COSV53756567; called by muse, mutect2, varscan2
- HCN4 | c.1692C>T p.F564= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs770857939, COSV56081217; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC9 | c.2553C>T p.F851= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV101287013; called by muse, mutect2, varscan2
- HHIPL2 | c.678G>A p.G226= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs761565368, COSV100597037; called by muse, mutect2, varscan2
- HTR1F | c.1020C>T p.S340= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1024864304, COSV100138225; called by muse, mutect2, varscan2
- HYDIN | c.6726G>A p.Q2242= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99993486; called by muse, mutect2, varscan2
- HYDIN | c.4449C>T p.I1483= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs1378393498, COSV66834509; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.249C>T p.F83= | Silent (SNP) | VAF 19/384 reads (5%) | catalogued as rs1163661836; called by muse, mutect2
- IGKV1-17 | c.279C>T p.F93= | Silent (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- IKZF3 | c.1065C>T p.A355= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99500067; called by muse, mutect2, varscan2
- INTS3 | c.2166C>T p.C722= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100016388; called by muse, mutect2, varscan2
- INTS3 | c.2167C>T p.L723= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100016392; called by muse, mutect2, varscan2
- ITGB4 | c.1020C>T p.F340= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as rs1315926190, COSV99564588; called by muse, mutect2, varscan2
- ITIH3 | c.1965C>T p.I655= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV101407102; called by muse, mutect2
- ITPKC | c.1662C>T p.I554= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs750786959, COSV54576766; called by muse, varscan2
- KALRN | c.7086C>T p.Y2362= (on ENST00000360013 / NM_001024660.4; = p.Y665= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99362725; called by muse, mutect2, varscan2
- KIFC2 | c.1536C>T p.F512= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1160762468, COSV100023951; called by muse, mutect2, varscan2
- KIR2DL1 | c.861G>A p.A287= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs373805813; called by muse, varscan2
- KLHL1 | c.1453C>T p.L485= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV64766775; called by muse, mutect2, varscan2
- KLK3 | c.57C>T p.P19= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100386082, COSV58102806; called by muse, mutect2
- KRBA1 | c.339C>T p.L113= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99753014; called by muse, mutect2, varscan2
- KRBA1 | c.1494C>T p.S498= | Silent (SNP) | VAF 51/212 reads (24%) | catalogued as rs1459318952, COSV99753019; called by muse, mutect2, varscan2
- KRTAP8-1 | c.33C>T p.F11= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV61597744; called by muse, mutect2, varscan2
- LAMB4 | c.2955C>T p.S985= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV99225227; called by muse, mutect2, varscan2
- LCN9 | c.384G>A p.R128= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs542930081, COSV99479616; called by muse, mutect2, varscan2
- LGALS12 | c.417C>T p.L139= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99737292; called by mutect2, varscan2
- LGI2 | c.888C>T p.L296= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV101180913; called by muse, mutect2, varscan2
- LMNA | c.1704C>T p.S568= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100738807; called by muse, mutect2, varscan2
- LRP1B | c.12295C>T p.L4099= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs763332949, COSV101259559; called by muse, mutect2, varscan2
- LRRC4C | c.684G>A p.G228= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs1159751894, COSV99539293; called by muse, mutect2, varscan2
- LTBP1 | c.1608C>T p.S536= (on ENST00000404816 / NM_206943.4; = p.S210= on NM_000627.4) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100617835; called by muse, mutect2, varscan2
- MAGEA6 | c.615C>T p.I205= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100262951; called by muse, mutect2, varscan2
- MAGEC3 | c.1572C>T p.F524= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100025945, COSV53577680; called by muse, mutect2, varscan2
- MAPKBP1 | c.2055C>T p.L685= (on ENST00000456763 / NM_001128608.2; = p.L679= on NM_014994.3) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99530001; called by muse, mutect2, varscan2
- MCOLN1 | c.60C>T p.P20= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs202247664, COSV99900788; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MDC1 | c.2856G>A p.E952= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100903033; called by muse, mutect2, varscan2
- MDH1B | c.144A>T p.L48= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100982270; called by muse, mutect2, varscan2
- MED23 | c.3078C>T p.L1026= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs771563986, COSV100645307; called by muse, varscan2
- MEDAG | c.657A>G p.G219= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100995313; called by muse, mutect2
- MFSD6L | c.495C>T p.F165= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV61001449; called by muse, mutect2, varscan2
- MICALL1 | c.1749C>T p.P583= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs545892604, COSV99317504; called by muse, mutect2, varscan2
- MMP14 | c.903C>T p.S301= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV100314267; called by muse, mutect2, varscan2
- MS4A2 | c.447C>T p.I149= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV54013733; called by muse, mutect2, varscan2
- MUC16 | c.22152C>T p.L7384= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1051285206, COSV101201001; called by muse, mutect2
- MUC16 | c.5820C>T p.S1940= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV67468177; called by muse, mutect2, varscan2
- MUSK | c.1998C>T p.F666= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV99504868; called by muse, mutect2, varscan2
- MYH11 | c.1932G>A p.K644= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100259884; called by muse, mutect2
- MYH2 | c.1572C>T p.I524= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV55430842; called by muse, mutect2, varscan2
- MYH4 | c.750C>T p.F250= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1244732876, COSV55111843, COSV55120205; called by muse, mutect2, varscan2
- MYO1B | c.1278G>A p.E426= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100269805; called by muse, mutect2, varscan2
- MYO5B | c.3144G>A p.Q1048= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV99546032; called by muse, mutect2, varscan2
- NADSYN1 | c.606C>T p.S202= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1201835017, COSV100034986; called by muse, mutect2, varscan2
- NCF2 | c.1143G>A p.K381= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as COSV100838930; called by muse, mutect2, varscan2
- NELL2 | c.2148C>T p.V716= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs757497843, COSV100420432; called by muse, varscan2
- NFASC | c.291G>A p.G97= (on ENST00000339876 / NM_001378329.1; = p.G91= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100365231; called by muse, mutect2, varscan2
- NLRP5 | c.273G>A p.S91= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs748240899, COSV101173841; called by muse, mutect2, varscan2
- NOBOX | c.453C>T p.T151= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs780060226, COSV56196136; called by muse, mutect2, varscan2
- NOD2 | c.2325C>T p.G775= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1029003758, COSV100318805; called by muse, mutect2
- NOTCH4 | c.4161G>A p.V1387= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs756869942, COSV100900907, COSV66682045; called by muse, mutect2
- NPC1L1 | c.684C>T p.A228= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs375746984; called by muse, mutect2, varscan2
- NPR3 | c.675G>A p.Q225= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99423697; called by muse, mutect2, varscan2
- NR1I2 | c.990G>A p.L330= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs1362104103, COSV100561670; called by muse, mutect2, varscan2
- NR5A2 | c.966C>T p.I322= (on ENST00000367362 / NM_205860.3; = p.I276= on NM_003822.5) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99371525; called by muse, mutect2, varscan2
- OCA2 | c.1563G>A p.L521= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs536116108, COSV100668456; called by muse, mutect2
- OGDHL | c.2031C>T p.L677= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100934469; called by muse, mutect2, varscan2
- OGDHL | c.432G>A p.L144= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100934470; called by muse, mutect2, varscan2
- OR10T2 | c.354G>A p.V118= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs1268900928, COSV57781871; called by muse, mutect2, varscan2
- OR1A1 | c.799C>T p.L267= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs770470632, COSV100410815; called by muse, mutect2, varscan2
- OR1B1 | c.633C>T p.F211= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100506525; called by muse, mutect2, varscan2
- OR2G3 | c.129C>T p.F43= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV100180715, COSV60681501; called by muse, mutect2, varscan2
- OR4A16 | c.645C>T p.S215= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100125362; called by muse, mutect2, varscan2
- OR4A16 | c.741C>A p.L247= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100125249, COSV59043426, COSV59045211; called by muse, mutect2, varscan2
- OR4D2 | c.129C>T p.I43= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV101613864; called by muse, mutect2, varscan2
- OR4N2 | c.732C>T p.I244= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV60050267; called by muse, mutect2, varscan2
- OR4Q3 | c.67C>T p.L23= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100057292; called by muse, mutect2, varscan2
- OR51A7 | c.546G>A p.Q182= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV63788777; called by muse, varscan2
- OR51B4 | c.786G>A p.G262= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs267602941, COSV66516849; called by muse, mutect2, varscan2
- OR56A3 | c.492C>T p.P164= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100290344; called by muse, mutect2, varscan2
- OR6C68 | c.159G>A p.L53= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV101110044; called by muse, mutect2, varscan2
- OR6M1 | c.250C>T p.L84= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs147909339; called by muse, mutect2, varscan2
- OR7D2 | c.915C>T p.L305= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100713050; called by muse, mutect2, varscan2
- OR8G2P | c.546C>T p.F182= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs767853605; called by muse, mutect2, varscan2
- OR8K5 | c.339C>T p.F113= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100537291; called by muse, mutect2, varscan2
- OSR2 | c.201C>T p.S67= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs1171352737, COSV99882759; called by muse, mutect2, varscan2
- OTOA | c.1383C>T p.V461= (on ENST00000286149; = p.V447= on NM_144672.4) | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV99625476; called by muse, mutect2, varscan2
- P2RX3 | c.729C>T p.I243= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV54443140, COSV54443283; called by mutect2, varscan2
- P3H2 | c.1356C>T p.F452= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs267599731, COSV60021707; called by muse, mutect2, varscan2
- P3H2 | c.525C>T p.F175= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs567532723, COSV60027706; called by muse, mutect2, varscan2
- PAK5 | c.303G>A p.R101= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV62031374; called by muse, mutect2, varscan2
- PCDHA8 | c.756C>T p.F252= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV65340529; called by muse, mutect2, varscan2
- PCDHA9 | c.1389C>T p.F463= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV65330020; called by muse, mutect2, varscan2
- PCDHB13 | c.2103C>T p.F701= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as COSV99507010; called by muse, mutect2, varscan2
- PCDHGB3 | c.1263G>A p.T421= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV53916783, COSV54032307; called by muse, mutect2, varscan2
- PDE6C | c.1614C>T p.F538= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV101008833; called by muse, mutect2, varscan2
- PEDS1 | c.483C>T p.A161= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100502171; called by muse, mutect2, varscan2
- PHC1 | c.1080G>A p.A360= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs757327886, COSV101418522, COSV101418682; called by muse, mutect2, varscan2
- PIK3IP1 | c.591G>A p.G197= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99314194; called by muse, mutect2
- PKD1L1 | c.4710G>A p.R1570= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV56969814; called by muse, mutect2, varscan2
- PLA2G12B | c.277C>T p.L93= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1169357076, COSV100888026; called by muse, mutect2
- PLD3 | c.1410C>T p.S470= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV52526587; called by muse, mutect2, varscan2
- PLSCR2 | c.840G>A p.V280= (on ENST00000497985 / NM_001199978.1; = p.V207= on NM_020359.2) | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100367873; called by muse, mutect2, varscan2
- PLXNA1 | c.5418C>T p.I1806= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99303911; called by muse, mutect2, varscan2
- POLR2F | c.117C>T p.L39= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as rs942829230, COSV101328965; called by muse, mutect2, varscan2
- PPARGC1A | c.1467C>T p.F489= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99338458; called by muse, mutect2, varscan2
- PROKR2 | c.522C>T p.I174= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs767395215, COSV54086725; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRSS36 | c.2103C>T p.H701= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99191315; called by muse, mutect2, varscan2
- PRSS54 | c.588C>T p.P196= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs1410661992, COSV99541173; called by muse, mutect2, varscan2
- PSG2 | c.39C>T p.I13= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV101290500; called by muse, mutect2, varscan2
- PTCD3 | c.1386C>T p.F462= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54483981; called by mutect2, varscan2
- PTCRA | c.786C>T p.S262= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100485815; called by muse, mutect2, varscan2
- PTOV1 | c.666G>A p.Q222= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as COSV99681966; called by muse, mutect2, varscan2
- PVR | c.786C>T p.A262= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV99495946; called by muse, mutect2, varscan2
- PXDNL | c.3652C>T p.L1218= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100685583; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1710C>T p.S570= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99770389; called by muse, mutect2, varscan2
- RAB3B | c.312C>T p.I104= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100862523, COSV65435202; called by muse, mutect2, varscan2
- RASGEF1A | c.1305G>A p.K435= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100988716; called by muse, mutect2, varscan2
- RBL1 | c.3138C>T p.V1046= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs146524033; called by muse, mutect2, varscan2
- RFTN1 | c.120C>T p.F40= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as COSV100489780; called by muse, mutect2, varscan2
- RGS9 | c.1539C>T p.F513= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV52224849; called by muse, mutect2, varscan2
- RHOH | c.48G>A p.G16= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs575059532, COSV101110547, COSV101110638; called by muse, mutect2, varscan2
- RIPK3 | c.825C>A p.S275= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99353401; called by muse, mutect2, varscan2
- RIPOR3 | c.1738C>T p.L580= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs751140022, COSV99246981; called by muse, mutect2, varscan2
86 further variants in this file (0 protein-altering or splice-affecting, 69 silent, 17 other) are not listed here.
